Gene-level copy-number profile of tumor specimen TCGA-IN-A6RO-01A from TCGA case TCGA-IN-A6RO, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 70.6 years (25,789 days).
Specimen TCGA-IN-A6RO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.fafd1ab7-0d9c-45b4-9e52-79d573f30afa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A6RO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cbc33f4-d467-485e-be6f-177f530522a3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2; copy number 2: 9,820; copy number 3: 15,864; copy number 4: 24,019; copy number 5: 6,244; copy number 6: 2,055; copy number 7: 453; copy number 8: 270; copy number 9: 436; copy number 10: 144; copy number 11: 15; copy number 12: 130; copy number 13: 125; copy number 14: 25; copy number 15: 68; copy number 17: 67; copy number 19: 1; copy number 23: 17; copy number 24: 14; copy number 41: 26; copy number 42: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A6RO-01A-12D-A33S-01): tumor purity 0.85, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,076 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:167,713,663–168,775,134, 9 genes, copy number 9 (within-gene range 7–9): CTAGE14P, B3GALT1-AS1, B3GALT1, STK39, PHF5GP, RN7SL813P, CERS6, MIR4774, RNU6-766P.
- chr2:169,577,371–171,587,259, 40 genes, copy number 9–12: AC093899.1, PPIG, CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38.
- chr2:201,643,398–203,315,871, 58 genes, copy number 10: AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11, RNU6-440P, AC069148.1, FZD7, KIAA2012, KIAA2012-AS1, AC079354.2, AC079354.1, PSMA2P3, DAZAP2P1, SUMO1, RPL39P14, NOP58, SNORD70, SNORD70B, SNORD11B, SNORD11, AC064836.3, RN7SL753P, PIMREGP1, AC064836.1, RN7SL40P, AC064836.2, BMPR2, H3P8, RPL13AP12, MTCO1P17, MTCO2P17, MTATP6P17, MTCO3P17, MTND3P17, MTND4LP17, MTND4P30, MTCO1P54, FAM117B, ICA1L, AC098831.1, KRT8P15, WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16, CYP20A1, RN7SL670P, MRPL50P2.
- chr2:203,328,459–203,329,226, 1 gene, copy number 10: AC080075.1.
- chr2:205,900,630–208,025,527, 65 genes, copy number 10–42 (within-gene range 3–42) (broad region; genes not listed).
- chr6:17,224,243–17,987,635, 15 genes, copy number 11 (within-gene range 2–11): AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1.
- chr6:19,143,695–21,523,783, 30 genes, copy number 9–14: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1.
- chr8:36,121,398–38,601,200, 69 genes, copy number 12 (broad region; genes not listed).
- chr11:92,498,152–92,498,935, 1 gene, copy number 10: RPS3AP42.
- chr11:93,144,174–93,197,991, 1 gene, copy number 9 (within-gene range 5–9): SLC36A4.
- chr11:93,171,134–101,872,562, 116 genes, copy number 9–12 (broad region; genes not listed).
- chr12:273,954–3,040,676, 65 genes, copy number 9–15 (within-gene range 5–15) (broad region; genes not listed).
- chr12:3,367,833–4,118,132, 15 genes, copy number 9–13: LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1.
- chr13:31,739,526–38,622,671, 94 genes, copy number 9–23 (broad region; genes not listed).
- chr13:39,209,116–48,303,661, 173 genes, copy number 9–17 (within-gene range 4–17) (broad region; genes not listed).
- chr13:48,316,863–48,341,330, 3 genes, copy number 9: PPP1R26P1, PCNPP5, AL392048.1.
- chr13:48,975,912–49,209,779, 1 gene, copy number 9 (within-gene range 4–9): FNDC3A.
- chr13:49,095,391–53,052,057, 102 genes, copy number 9 (broad region; genes not listed).
- chr13:53,815,419–54,986,720, 8 genes, copy number 10: LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1.
- chr16:3,611,728–5,097,795, 61 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr17:39,156,894–40,565,472, 66 genes, copy number 10–41 (broad region; genes not listed).
- chr19:28,869,507–32,244,083, 60 genes, copy number 9–13: AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, AC074139.1, RNA5SP472.
- chr19:37,371,061–37,906,677, 23 genes, copy number 12: ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
